Somatic mutation profile of tumor specimen MP2PRT-PAVENH-TBP1-A (aliquot MP2PRT-PAVENH-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVENH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (594 days).
Specimen MP2PRT-PAVENH-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e01b79b-009f-4b08-93e9-8eb5a9bdc396.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVENH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVENH-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7547458e-c0f7-427b-a791-2671bc909802

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SORCS3 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1476280805; called by muse, mutect2, varscan2
- UNC5A | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 25/451 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1228167410; called by muse, mutect2
- ZC3HAV1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 42/748 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1196739916, COSV54295707; called by muse, mutect2
- PKHD1L1 | c.10987G>A p.D3663N | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.189); called by muse, mutect2
- SPG11 | c.6073G>A p.A2025T | Missense Mutation (SNP) | VAF 28/570 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.165); called by muse, mutect2
- TMEM151B | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 98/619 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CRHR2 | c.678C>G p.L226= | Silent (SNP) | VAF 10/331 reads (3%) | called by muse, mutect2
- ITGA8 | c.2673C>T p.S891= | Silent (SNP) | VAF 32/334 reads (10%) | catalogued as rs142740699; called by muse, mutect2
- PRSS16 | c.195G>T p.L65= | Silent (SNP) | VAF 50/367 reads (14%) | called by muse, mutect2, varscan2
- RIMBP2 | c.1749C>T p.P583= | Silent (SNP) | VAF 64/637 reads (10%) | catalogued as rs778976176; called by muse, mutect2
- KCNQ1 | c.1393+31899G>C | Intron (SNP) | VAF 43/355 reads (12%) | called by muse, mutect2, varscan2
- SHANK2 | c.1854-60G>A | Intron (SNP) | VAF 15/350 reads (4%) | catalogued as rs782361805; called by muse, mutect2
